Somatic mutation profile of tumor specimen ALCH-B2SD-TTP1-A (aliquot ALCH-B2SD-TTP1-A-2-0-D-A78Q-36) from ALCHEMIST case ALCH-B2SD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 52.9 years (19,326 days).
Specimen ALCH-B2SD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57ad9111-1040-4058-9586-a9dfc62e1013.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2SD-NB1-A (Blood Derived Normal), aliquot ALCH-B2SD-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2090957f-0502-4691-8923-2c25b117f8a2

The open-access MAF lists 337 somatic variants for this specimen: 241 protein-altering or splice-affecting, 60 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 214, Silent 60, Intron 16, Nonsense Mutation 12, Frame Shift Del 10, RNA 7, 3'UTR 7, 5'UTR 4, Splice Region 3, Splice Site 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 75/203 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 22/110 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 8/65 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACOX1 | c.1186T>A p.C396S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1221063213; called by muse, mutect2, varscan2
- ADD1 | c.2143C>G p.P715A | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1023677538; called by muse, mutect2, varscan2
- ANGPT1 | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs761722439; called by muse, mutect2, varscan2
- ARHGAP35 | c.3785C>T p.P1262L | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68333148; called by muse, mutect2, varscan2
- ARSK | c.702G>C p.V234= | Splice Region (SNP) | VAF 26/197 reads (13%) | catalogued as COSV101187577; called by muse, varscan2
- C1orf87 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1375957108; called by mutect2, varscan2
- CC2D1A | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775951098; called by muse, mutect2, varscan2
- CDH5 | c.2323G>A p.G775S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as rs372602492; called by muse, varscan2
- CHCHD6 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV52066851; called by muse, mutect2
- CPS1 | c.1386G>C p.M462I | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV99242402; called by muse, mutect2, varscan2
- CSMD1 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs748546639; called by muse, mutect2, varscan2
- CTNND2 | c.199C>G p.R67G | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV58867697; called by muse, mutect2, varscan2
- CTNND2 | c.91del p.L31* | Frame Shift Del (DEL) | VAF 17/148 reads (11%) | catalogued as COSV58934837; called by mutect2, pindel, varscan2
- CXXC1 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV53275629; called by muse, mutect2, varscan2
- CYBB | c.565A>T p.I189F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as CD015961; called by muse, mutect2, varscan2
- DDX53 | c.1544G>C p.S515T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60069213; called by muse, mutect2, varscan2
- DNAH3 | c.10010C>T p.T3337M | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs530510705, COSV54505745; called by muse, mutect2
- DNAH6 | c.10433C>A p.A3478E | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52849369; called by muse, mutect2
- ELAC2 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as rs765484266; called by muse, mutect2
- FCRL3 | c.1932G>T p.M644I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100943595, COSV63839173; called by muse, mutect2, varscan2
- FH | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD104350; called by muse, mutect2, varscan2
- FKBP1C | c.203G>T p.S68I | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62179571; called by muse, mutect2
- FLG | c.10511C>A p.S3504* | Nonsense Mutation (SNP) | VAF 52/146 reads (36%) | catalogued as COSV64251559; called by muse, mutect2, varscan2
- FRG2B | c.529A>C p.T177P | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV71042895; called by muse, mutect2
- FSTL5 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV60193580; called by muse, mutect2
- GAS2L2 | c.121T>C p.W41R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782798675; called by muse, mutect2, varscan2
- GCN1 | c.3031A>G p.T1011A | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1314534479; called by muse, mutect2
- GPC5 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.746); catalogued as rs1359112608; called by muse, varscan2
- GPR4 | c.212C>G p.P71R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59916200; called by muse, varscan2
- H2AX | c.127C>G p.R43G | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1306834186, COSV53827394; called by muse, mutect2, varscan2
- HEY1 | c.97A>T p.S33C | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.784); catalogued as rs1390826319; called by muse, mutect2, varscan2
- HS3ST4 | c.813del p.K272Sfs*12 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | catalogued as COSV100501716; called by mutect2, pindel, varscan2
- IMPG2 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99516803; called by muse, mutect2
- KCNMB4 | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs772023848; called by muse, mutect2, varscan2
- KLHL1 | c.2199G>C p.L733F | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV64770258; called by muse, mutect2, varscan2
- LBP | c.965G>T p.R322L | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as rs373530154, COSV99461594; called by muse, mutect2
- LMX1A | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.231); catalogued as COSV54220753; called by muse, mutect2, varscan2
- LRP2 | c.7370C>T p.T2457I | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.099); catalogued as rs1397837827; called by muse, mutect2
- MAP3K4 | c.2156C>T p.S719L | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV62331413; called by muse, mutect2
- MON2 | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99742774; called by muse, mutect2
- MRGPRF | c.902G>T p.R301L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57995965, COSV57996092; called by muse, mutect2, varscan2
- MUC16 | c.41603C>A p.P13868H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101110094; called by muse, mutect2, varscan2
- MYH1 | c.1214C>A p.P405H | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876231; called by muse, mutect2, varscan2
- NBEA | c.3905G>A p.R1302Q | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs746740466, COSV100077428, COSV59791280; called by muse, mutect2, varscan2
- NCOR1 | c.1879C>G p.R627G | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV51984309, COSV51992684, COSV52001655; called by muse, mutect2
- NDN | c.550del p.R184Afs*4 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | catalogued as COSV59359889; called by mutect2, pindel, varscan2
- NID2 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs201741158, COSV53503170, COSV53503828; called by muse, mutect2, varscan2
- NMBR | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV57801383; called by muse, mutect2, varscan2
- PCDHB11 | c.2335C>T p.L779F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV100697010; called by muse, mutect2
- PI4KA | c.5953G>T p.G1985C | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356764362; called by muse, mutect2, varscan2
- POTEC | c.174G>T p.R58S | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV100744043, COSV62802752; called by muse, mutect2, varscan2
- POTEC | c.173G>T p.R58M | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100744067, COSV62801723; called by muse, mutect2, varscan2
- PPARGC1A | c.1187T>C p.I396T | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.549); catalogued as rs1343287573; called by muse, mutect2, varscan2
- PTGFR | c.1000del p.E334Sfs*9 | Frame Shift Del (DEL) | VAF 20/150 reads (13%) | catalogued as COSV66114272; called by mutect2, pindel, varscan2
- PTPN3 | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV52704420; called by muse, mutect2, varscan2
- SCN1A | c.5347G>T p.A1783S (on ENST00000303395 / NM_001202435.3; = p.A1772S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM072003; called by muse, mutect2, varscan2
- SLITRK3 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53848848, COSV53850739, COSV53853797; called by muse, mutect2
- SRRM2 | c.1669G>T p.A557S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as COSV100070561; called by muse, mutect2, varscan2
- STAB1 | c.3304G>A p.A1102T | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.441); catalogued as rs1199653660; called by muse, mutect2, varscan2
- STAB2 | c.5540G>T p.G1847V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); catalogued as COSV66339549; called by muse, mutect2, varscan2
- TGFB1I1 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV62357867; called by muse, mutect2, varscan2
- TNS4 | c.2039A>G p.E680G | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV54188140; called by muse, mutect2, varscan2
- UBR4 | c.13721A>G p.N4574S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.982); catalogued as rs768098413; called by muse, mutect2, varscan2
- UHRF1 | c.971G>A p.R324Q (on ENST00000612630 / NM_001290050.1; = p.R337Q on NM_013282.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs1203961237; called by muse, mutect2, varscan2
- UNC13C | c.4315G>A p.A1439T | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs759500801; called by muse, mutect2, varscan2
- VPS13A | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs1320910987; called by muse, mutect2, varscan2
- WBP2 | c.398-7C>T | Splice Region (SNP) | VAF 14/144 reads (10%) | catalogued as rs1432132146; called by muse, mutect2
- WWC2 | c.2123A>G p.Y708C | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1346661672; called by muse, mutect2, varscan2
- ZBP1 | c.1099C>A p.R367S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100473815; called by muse, mutect2, varscan2
- AC104389.6 | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ACE | c.1240C>G p.P414A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- ACSM5 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2
- ADAD1 | c.1618T>C p.C540R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4818G>A p.W1606* | Nonsense Mutation (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- ADH1B | c.493T>A p.S165T | Missense Mutation (SNP) | VAF 109/397 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- AL445989.1 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 79/361 reads (22%) | SIFT tolerated, low confidence (0.7); called by muse, mutect2, varscan2
- ANO3 | c.779A>G p.Q260R | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- AP2B1 | c.2720C>G p.P907R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); called by muse, mutect2
- ARID5A | c.56A>T p.D19V | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- ATP13A4 | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ATP9A | c.2381A>T p.Q794L | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BIRC6 | c.12880G>T p.G4294C | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPIFB4 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.063); called by muse, mutect2
- C11orf53 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- CADM3 | c.1166G>T p.G389V (on ENST00000368125 / NM_001127173.3; = p.G423V on NM_021189.5) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CAPS2 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 52/367 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CCDC60 | c.1270G>T p.V424F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- CCDC81 | c.1408G>A p.A470T (on ENST00000445632 / NM_001156474.2; = p.A380T on NM_021827.4) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- CCT8L2 | c.920C>A p.A307E | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CD36 | c.1316A>G p.N439S | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDC123 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CDCA7L | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- CDH18 | c.1087C>A p.P363T | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CFAP70 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- CHD7 | c.477del p.Y160Tfs*51 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, varscan2
- CLCA4 | c.2552G>T p.S851I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CLCNKA | c.1493C>A p.A498E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CNTNAP2 | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 66/324 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- COL11A1 | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- COQ8B | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPSF1 | c.4111C>G p.P1371A | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.068); called by muse, mutect2
- CRHR2 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- CROT | c.1786A>T p.T596S | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2
- CSE1L | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- CTLA4 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- CTNND1 | c.583G>T p.G195W | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CUL5 | c.911C>G p.P304R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CYP21A2 | c.1387C>A p.Q463K | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.012); called by muse, mutect2
- DIP2B | c.4102-1G>T p.X1368_splice | Splice Site (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- DLG2 | c.332C>T p.S111L (on ENST00000650630 / NM_001351274.2; = p.S74L on NM_001142699.3) | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSEL | c.1780G>T p.V594F | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- DYNC2H1 | c.4503T>A p.N1501K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DZIP1L | c.1037A>T p.E346V | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- EEA1 | c.1741A>G p.T581A | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.079); called by mutect2, varscan2
- EFEMP1 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- EXOC5 | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- F7 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCRL3 | c.1226G>C p.G409A | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FGF10 | c.129C>A p.D43E | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FLNC | c.4244G>C p.G1415A | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- FOXD4L6 | c.999del p.S334Qfs*94 | Frame Shift Del (DEL) | VAF 48/256 reads (19%) | called by mutect2, pindel, varscan2
- FSTL5 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- FYB1 | c.293T>A p.L98* | Nonsense Mutation (SNP) | VAF 24/195 reads (12%) | called by muse, mutect2, varscan2
- GLT1D1 | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- GNAO1 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- GPR179 | c.4991C>T p.P1664L (on ENST00000621958; = p.P1663L on NM_001004334.4) | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- HJURP | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.075); called by mutect2, varscan2
- HPCAL4 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- HSPG2 | c.13004-3C>T | Splice Region (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- HSPG2 | c.11650C>T p.Q3884* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- HTATSF1 | c.1559A>T p.E520V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- IGF2 | c.335C>A p.A112E (on ENST00000434045 / NM_001127598.3; = p.A56E on NM_000612.6) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- IGHG4 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- IGLV2-18 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- IL12B | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- IL21R | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ITPR1 | c.2110A>T p.S704C (on ENST00000354582; = p.S689C on NM_002222.7) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); called by muse, mutect2
- KCNB1 | c.2417del p.P806Lfs*4 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | called by mutect2, pindel
- KLHL2 | c.1151C>A p.A384D | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2
- LAMA1 | c.4175G>T p.G1392V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LGR6 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- LILRB2 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- LINGO2 | c.1160C>A p.T387N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMO4 | c.410G>C p.C137S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LOXHD1 | c.693del p.Q232Sfs*2 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- LRRC41 | c.2161G>T p.A721S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAGEA3 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- MAN2A1 | c.378T>A p.N126K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- MEAF6 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MFNG | c.331T>A p.S111T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- MGAM | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MRC1 | c.3049G>T p.E1017* | Nonsense Mutation (SNP) | VAF 36/353 reads (10%) | called by muse, mutect2, varscan2
- MROH2B | c.3967G>A p.A1323T | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- MTHFD1L | c.777C>G p.S259R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.129); called by muse, mutect2
- MUC15 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- MUC4 | c.12139A>G p.T4047A | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.689); called by muse, varscan2
- MUC4 | c.7612T>C p.S2538P | Missense Mutation (SNP) | VAF 107/724 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- MUC5B | c.5059G>A p.G1687R | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.142); called by muse, mutect2
- MUC5B | c.17002T>C p.W5668R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBR1 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NF1 | c.6315C>A p.H2105Q (on ENST00000358273 / NM_001042492.3; = p.H2084Q on NM_000267.3) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NPAP1 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- NR1H3 | c.582del p.R195Gfs*19 | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | called by mutect2, pindel, varscan2
- NTRK2 | c.1498G>T p.A500S (on ENST00000323115 / NM_001369534.1; = p.A516S on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- NUP43 | c.54G>C p.W18C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- NYAP1 | c.485A>T p.Q162L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.943); called by muse, mutect2
- OR10W1 | c.353G>T p.C118F | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2
- OR2AP1 | c.529T>G p.C177G | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2J2 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- OR2W3 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51A2 | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR52I2 | c.167G>C p.W56S | Missense Mutation (SNP) | VAF 34/367 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- OR9A2 | c.368_369del p.C123* | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | called by pindel, varscan2
- PAPPA2 | c.1967G>A p.C656Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH1 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.14046G>T p.K4682N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCYT1B | c.719A>T p.Y240F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, varscan2
- PEPD | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PER2 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PGK2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- PIK3CG | c.3087C>G p.I1029M | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- PLA2G15 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PLA2R1 | c.2522G>T p.S841I | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PLAC1 | c.94A>T p.I32L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- POTEB3 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, varscan2
- PPP1R7 | c.906+1G>A p.X302_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- PRELID1 | c.23A>T p.Q8L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCG | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PTPN3 | c.2414A>C p.Q805P | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RBBP6 | c.1223C>A p.P408H | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- RECQL | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RPS10 | c.457G>C p.V153L (on ENST00000644700; = p.X152_splice on NM_001014.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- RPS4Y2 | c.448C>G p.P150A | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- RTL4 | c.576C>A p.N192K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by mutect2, varscan2
- SCN11A | c.4900G>T p.D1634Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC14L3 | c.598G>C p.V200L | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.148); called by muse, mutect2
- SEC16A | c.3446C>G p.P1149R | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SERPINB2 | c.248A>T p.Q83L | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SFRP1 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SLC28A3 | c.1373T>G p.L458R | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC35A1 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC47A2 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A4 | c.571T>A p.S191T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- SMG9 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SNRPA | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SOCS4 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRGAP2 | c.1807G>A p.V603I (on ENST00000624873 / NM_001170637.4; = p.V604I on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SYCP2L | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 10/145 reads (7%) | called by muse, mutect2
- TBC1D16 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- TCF19 | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- TCN1 | c.701A>T p.E234V | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- TDRD6 | c.4225G>A p.A1409T | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.622); called by muse, mutect2
- TMC8 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM132C | c.2971C>A p.Q991K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- TNIK | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- TRA2B | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2
- TTN | c.36492C>A p.N12164K (on ENST00000591111; = p.N4740K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TTN | c.22204G>A p.V7402M (on ENST00000591111; = p.V6475M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- TUBB2B | c.557C>A p.T186N | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- UNC80 | c.3245C>A p.P1082H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2
- USH2A | c.6022G>A p.E2008K | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); called by muse, mutect2
- USHBP1 | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- WWP1 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- XRN1 | c.2893G>T p.E965* | Nonsense Mutation (SNP) | VAF 41/227 reads (18%) | called by muse, mutect2, varscan2
- ZFPM2 | c.2192G>C p.R731T | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ZMYM2 | c.2323G>A p.G775R | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF251 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.258); called by muse, mutect2
- ZNF292 | c.2513T>G p.V838G | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF318 | c.3643A>T p.K1215* | Nonsense Mutation (SNP) | VAF 37/207 reads (18%) | called by muse, mutect2, varscan2
- ZNF397 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.69); called by muse, mutect2
- ZNF479 | c.48G>C p.L16F | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, varscan2
- ZNF676 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 44/257 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF705A | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF724 | c.219A>T p.K73N | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF726 | c.57G>C p.Q19H | Missense Mutation (SNP) | VAF 57/382 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF770 | c.954A>T p.R318S | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZSWIM6 | c.1942C>A p.R648S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ACTL7B | c.441G>A p.V147= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- ADAM22 | c.492G>T p.G164= | Silent (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- ADAMTSL1 | c.1317A>G p.K439= | Silent (SNP) | VAF 59/162 reads (36%) | called by muse, mutect2, varscan2
- AK5 | c.675C>A p.A225= (on ENST00000354567 / NM_174858.3; = p.A199= on NM_012093.4) | Silent (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- ANGPT1 | c.654C>T p.N218= | Silent (SNP) | VAF 35/262 reads (13%) | called by muse, mutect2, varscan2
- CAPRIN2 | c.1038G>A p.K346= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV99195434; called by muse, mutect2, varscan2
- CDH26 | c.672T>C p.S224= | Silent (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
- CFAP46 | c.3363T>C p.H1121= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2
- CHD2 | c.2301G>C p.L767= | Silent (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- CIBAR2 | c.708C>T p.A236= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs748892560; called by mutect2, varscan2
- CPS1 | c.876A>T p.G292= | Silent (SNP) | VAF 20/279 reads (7%) | called by muse, mutect2
- CPS1 | c.993C>T p.F331= | Silent (SNP) | VAF 9/186 reads (5%) | catalogued as COSV51822760; called by muse, mutect2
- CROCC2 | c.2640C>G p.L880= | Silent (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- CSMD3 | c.7389A>T p.L2463= (on ENST00000297405 / NM_001363185.1; = p.L2359= on NM_052900.3) | Silent (SNP) | VAF 32/285 reads (11%) | called by muse, mutect2, varscan2
- CSMD3 | c.1582C>A p.R528= (on ENST00000297405 / NM_001363185.1; = p.R424= on NM_052900.3) | Silent (SNP) | VAF 37/314 reads (12%) | catalogued as rs138791171; called by muse, mutect2, varscan2
- DCN | c.723G>C p.L241= | Silent (SNP) | VAF 45/268 reads (17%) | catalogued as COSV99272350; called by muse, mutect2, varscan2
- DNAH9 | c.7905G>A p.L2635= | Silent (SNP) | VAF 44/251 reads (18%) | called by muse, mutect2, varscan2
- DTNA | c.1230G>A p.G410= | Silent (SNP) | VAF 30/232 reads (13%) | called by muse, mutect2, varscan2
- ELMO1 | c.336G>C p.R112= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as COSV60300231; called by muse, mutect2, varscan2
- ENPEP | c.2601C>A p.A867= | Silent (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- FAP | c.1647A>G p.V549= | Silent (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2
- FCRL5 | c.2328G>C p.L776= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV62512484, COSV62518894; called by muse, mutect2
- FGA | c.2454T>C p.N818= | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- GASK1B | c.639C>T p.P213= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as rs1382578136, COSV99647600; called by muse, mutect2, varscan2
- GLI2 | c.267C>T p.L89= | Silent (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- GNAS | c.702G>A p.G234= | Silent (SNP) | VAF 41/176 reads (23%) | called by muse, mutect2, varscan2
- GPHN | c.291A>T p.P97= | Silent (SNP) | VAF 90/328 reads (27%) | called by muse, mutect2, varscan2
- HTR1F | c.246G>A p.V82= | Silent (SNP) | VAF 59/267 reads (22%) | called by muse, mutect2, varscan2
- LIPE | c.637C>T p.L213= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs1244913821; called by muse, mutect2, varscan2
- LPAR4 | c.816T>C p.Y272= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- LYST | c.7413C>G p.L2471= | Silent (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- MAPK12 | c.196C>T p.L66= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as rs1422168489; called by muse, mutect2
- MDM1 | c.513G>A p.L171= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1308366814; called by muse, mutect2, varscan2
- MUC4 | c.7773C>G p.T2591= | Silent (SNP) | VAF 49/542 reads (9%) | catalogued as rs1482392588; called by muse, varscan2
- MYH13 | c.654A>G p.L218= | Silent (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- MYH4 | c.3388C>A p.R1130= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as rs772548795; called by mutect2, varscan2
- NCAM1 | c.978T>A p.T326= | Silent (SNP) | VAF 25/183 reads (14%) | called by muse, mutect2, varscan2
- OR5K2 | c.255C>T p.F85= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as COSV71143551; called by muse, mutect2, varscan2
- PCDHGB4 | c.2139G>C p.L713= | Silent (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- PHF21B | c.939C>T p.Y313= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as rs1439136606; called by muse, mutect2
- PIKFYVE | c.2433T>C p.Y811= | Silent (SNP) | VAF 29/238 reads (12%) | called by muse, mutect2, varscan2
- POP4 | c.165G>T p.A55= | Silent (SNP) | VAF 45/191 reads (24%) | called by muse, mutect2, varscan2
- PTPRQ | c.1059C>T p.N353= (on ENST00000616559; = p.N311= on NM_001145026.2) | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as rs1443928817; called by muse, mutect2, varscan2
- PTPRR | c.1692C>A p.L564= | Silent (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- ROBO2 | c.4008T>C p.S1336= | Silent (SNP) | VAF 38/142 reads (27%) | called by muse, mutect2, varscan2
- SLITRK1 | c.468G>A p.L156= | Silent (SNP) | VAF 50/207 reads (24%) | called by muse, mutect2, varscan2
- SRRM2 | c.1668A>T p.S556= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs761204756; called by muse, mutect2, varscan2
- SRRM4 | c.528G>T p.R176= | Silent (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- SSBP4 | c.1080C>T p.G360= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs962552254; called by muse, mutect2, varscan2
- ST18 | c.2568C>A p.S856= | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as COSV52494876; called by muse, mutect2
- STON1-GTF2A1L | c.2481G>A p.V827= | Silent (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- SYNE3 | c.1527C>A p.I509= | Silent (SNP) | VAF 48/182 reads (26%) | catalogued as COSV62078202, COSV62078834; called by muse, mutect2, varscan2
- TAT | c.228G>T p.L76= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- THOC6 | c.102A>G p.P34= | Silent (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- TNPO1 | c.468A>T p.A156= | Silent (SNP) | VAF 34/192 reads (18%) | called by muse, mutect2, varscan2
- TYR | c.1125C>T p.S375= | Silent (SNP) | VAF 29/220 reads (13%) | called by muse, mutect2, varscan2
- WDR36 | c.411C>G p.V137= | Silent (SNP) | VAF 41/393 reads (10%) | called by muse, mutect2, varscan2
- ZFHX2 | c.549T>C p.S183= | Silent (SNP) | VAF 65/138 reads (47%) | called by muse, mutect2, varscan2
- ZNF616 | c.1887A>G p.G629= | Silent (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2
- ZNF776 | c.157C>T p.L53= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs773072194; called by muse, mutect2, varscan2
- ADRA1A | c.884-8696G>A | Intron (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- ALG10B | c.-50del | 5'UTR (DEL) | VAF 17/131 reads (13%) | called by mutect2, pindel
- BBS4 | c.*302G>C | 3'UTR (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- C15orf61 | c.346+482T>C | Intron (SNP) | VAF 8/92 reads (9%) | catalogued as rs893523188; called by muse, mutect2
- CA3 | c.-15C>T | 5'UTR (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99570916; called by muse, mutect2, varscan2
- COL14A1 | c.5312-809C>A | Intron (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- COL1A2 | c.2296-18C>A | Intron (SNP) | VAF 57/437 reads (13%) | called by muse, mutect2, varscan2
- EPB41L1 | c.1669-2736C>T | Intron (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- FMR1 | c.*54A>G | 3'UTR (SNP) | VAF 36/114 reads (32%) | catalogued as COSV99502989; called by muse, mutect2, varscan2
- FOSB | c.447+77G>T | Intron (SNP) | VAF 3/14 reads (21%) | catalogued as rs1257333095; called by muse, mutect2
- FUNDC2P2 | n.523A>G | RNA (SNP) | VAF 52/212 reads (25%) | catalogued as rs571958910; called by muse, mutect2, varscan2
- HBD | c.*19G>A | 3'UTR (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2, varscan2
- HOXA7 | chr7:27153001 G>C | 3'Flank (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- IGFBP6 | c.334+1271C>T | Intron (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- INSR | c.*34C>T | 3'UTR (SNP) | VAF 12/75 reads (16%) | catalogued as COSV100253278; called by muse, mutect2, varscan2
- LINC00470 | n.1527C>A | RNA (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18585C>A | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18586C>G | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- MAF | c.-49G>A | 5'UTR (SNP) | VAF 22/82 reads (27%) | catalogued as rs776506070; called by muse, mutect2, varscan2
- NBPF22P | n.1225G>C | RNA (SNP) | VAF 18/320 reads (6%) | called by muse, mutect2
- ORC4 | c.762+42G>T | Intron (SNP) | VAF 14/85 reads (16%) | called by muse, varscan2
- P2RY12 | c.*30C>G | 3'UTR (SNP) | VAF 9/142 reads (6%) | catalogued as COSV99850827, COSV99854481; called by muse, mutect2
- RUFY3 | chr4:70793883 T>G | 3'Flank (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- SF1 | c.236+33C>T | Intron (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2, varscan2
- SGCD | c.189+49078C>A | Intron (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- SNORD115-34 | n.5del | RNA (DEL) | VAF 32/209 reads (15%) | called by mutect2, pindel, varscan2
- SNX29 | c.247+2193T>G | Intron (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- SPSB4 | c.-10G>A | 5'UTR (SNP) | VAF 7/81 reads (9%) | catalogued as COSV60147961; called by muse, mutect2
- TP63 | c.*48C>A | 3'UTR (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.1372-39G>C | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- UBE2DNL | n.375C>A | RNA (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- UBE2DNL | n.376A>G | RNA (SNP) | VAF 15/62 reads (24%) | catalogued as rs1212136237; called by muse, mutect2, varscan2
- UBTFL2 | n.785A>T | RNA (SNP) | VAF 51/326 reads (16%) | called by muse, mutect2, varscan2
- UNKL | c.852+25G>A | Intron (SNP) | VAF 8/41 reads (20%) | catalogued as rs372559366; called by muse, mutect2
- ZNF268 | c.33+2640G>C | Intron (SNP) | VAF 14/84 reads (17%) | called by mutect2, varscan2
- ZNF99 | c.*729C>A | 3'UTR (SNP) | VAF 31/284 reads (11%) | called by muse, varscan2
